Somatic mutation profile of tumor specimen TCGA-A7-A0DB-01A (aliquot TCGA-A7-A0DB-01A-11W-A019-09) from TCGA case TCGA-A7-A0DB, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 56.3 years (20,570 days).
Specimen TCGA-A7-A0DB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f77e806-537f-40e9-b33b-b28af74a7a7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A7-A0DB-10A (Blood Derived Normal), aliquot TCGA-A7-A0DB-10A-02D-A272-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c9b0f52-0abf-4094-96cb-8511d091ab66

The open-access MAF lists 39 somatic variants for this specimen: 27 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 23, Silent 12, Frame Shift Ins 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 140/314 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAA1 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as rs1340762162, COSV57179388; called by muse, mutect2, varscan2
- ADNP2 | c.1790C>G p.S597C | Missense Mutation (SNP) | VAF 71/133 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV51541989; called by muse, mutect2, varscan2
- BDP1 | c.1183A>G p.K395E | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs1285423349, COSV62434163; called by muse, mutect2, varscan2
- CCKBR | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs749874540, COSV58100133; called by muse, mutect2, varscan2
- CD163L1 | c.2926C>A p.L976M | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.591); catalogued as COSV58010744, COSV58023412; called by muse, mutect2, varscan2
- CEACAM20 | c.1740G>C p.E580D | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.113); catalogued as COSV57603084; called by muse, mutect2, varscan2
- FBN3 | c.8236G>A p.E2746K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs780590806, COSV53664292; called by muse, mutect2, varscan2
- HEATR1 | c.6345A>C p.E2115D | Missense Mutation (SNP) | VAF 63/392 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59382639; called by muse, mutect2, varscan2
- KRT25 | c.911G>T p.R304L | Missense Mutation (SNP) | VAF 25/253 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV56443482, COSV56446351; called by muse, mutect2, varscan2
- LRRC14 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.3); catalogued as rs755544856, COSV52881678; called by muse, mutect2
- PEDS1-UBE2V1 | c.910T>G p.F304V | Missense Mutation (SNP) | VAF 238/650 reads (37%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.135); catalogued as rs761220005, COSV59015503; called by mutect2, varscan2
- SCN2A | c.5632C>A p.Q1878K | Missense Mutation (SNP) | VAF 67/283 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV51853394; called by muse, mutect2, varscan2
- SLC9A2 | c.1390G>T p.A464S | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as COSV52136935; called by muse, mutect2
- SYNE2 | c.1818G>C p.K606N | Missense Mutation (SNP) | VAF 60/683 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV59967069; called by muse, mutect2
- SYNE2 | c.12647C>G p.S4216C | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.41); catalogued as COSV59967077; called by muse, mutect2, varscan2
- TSHZ3 | c.1637dup p.Y547Lfs*35 | Frame Shift Ins (INS) | VAF 19/160 reads (12%) | catalogued as rs750388867; called by mutect2, varscan2
- WNK1 | c.5356C>G p.L1786V (on ENST00000315939 / NM_018979.4; = p.L1539V on NM_014823.3) | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); catalogued as COSV60043672; called by muse, mutect2, varscan2
- WNT5B | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV60198884; called by muse, mutect2, varscan2
- YLPM1 | c.5716G>C p.E1906Q | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53119378; called by muse, mutect2, varscan2
- ZNF432 | c.1407G>C p.K469N | Missense Mutation (SNP) | VAF 37/268 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.907); catalogued as COSV55418199; called by muse, mutect2, varscan2
- ZNF506 | c.233A>G p.Y78C | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71354659; called by muse, mutect2, varscan2
- COL6A6 | c.3904T>G p.F1302V | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MAP3K1 | c.1368dup p.T457Yfs*4 | Frame Shift Ins (INS) | VAF 82/196 reads (42%) | called by mutect2, varscan2
- MAP3K1 | c.2012_2013dup p.E672Rfs*14 | Frame Shift Ins (INS) | VAF 66/343 reads (19%) | called by mutect2, varscan2
- MTM1 | c.1140C>A p.D380E | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NUP210L | c.3280C>A p.L1094M | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2
- ATG9B | c.879G>T p.L293= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV65059494; called by muse, mutect2, varscan2
- EHD1 | c.588C>T p.I196= | Silent (SNP) | VAF 36/61 reads (59%) | catalogued as rs759743110, COSV57736482; called by muse, mutect2, varscan2
- H2AC12 | c.360G>A p.K120= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as rs766851091, COSV63617147; called by muse, mutect2, varscan2
- LCE3D | c.237C>T p.G79= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as rs61745173, COSV64230550; called by muse, mutect2
- LPIN3 | c.2457G>A p.V819= | Silent (SNP) | VAF 30/51 reads (59%) | catalogued as COSV60038444; called by muse, mutect2, varscan2
- LSMEM1 | c.108C>G p.A36= | Silent (SNP) | VAF 52/225 reads (23%) | catalogued as COSV57197070; called by muse, mutect2, varscan2
- NGEF | c.24T>C p.D8= | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as COSV50948845; called by muse, mutect2, varscan2
- NUDT11 | c.345G>A p.R115= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV65665447; called by muse, mutect2, varscan2
- NUDT6 | c.906T>C p.H302= | Silent (SNP) | VAF 32/124 reads (26%) | catalogued as COSV52652584; called by muse, mutect2, varscan2
- SPTA1 | c.4998G>A p.L1666= | Silent (SNP) | VAF 21/259 reads (8%) | catalogued as COSV63758246; called by muse, mutect2
- SRSF5 | c.786A>T p.R262= | Silent (SNP) | VAF 35/273 reads (13%) | catalogued as COSV53683800; called by muse, mutect2, varscan2
- ZNF749 | c.1977G>A p.Q659= | Silent (SNP) | VAF 92/458 reads (20%) | catalogued as COSV61947981; called by muse, mutect2, varscan2
